Somatic mutation profile of tumor specimen MMRF_1596_1_BM_CD138pos (aliquot MMRF_1596_1_BM_CD138pos_T1_KBS5U_L04118) from MMRF case MMRF_1596, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.2 years (24,542 days).
Specimen MMRF_1596_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fced864-53f1-43d1-bd46-8029aabdc39b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1596_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1596_1_PB_Whole_C2_KBS5U_L04124; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/573e71a5-8de8-4a6a-bc9f-654c418f78cc

The open-access MAF lists 124 somatic variants for this specimen: 43 protein-altering or splice-affecting, 21 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 32, Silent 21, Intron 13, 5'Flank 6, 3'Flank 5, 5'UTR 2, RNA 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4502G>A p.C1501Y | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as rs139550875; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2739G>T p.K913N | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1185592391; called by muse, mutect2
- CCDC14 | c.2131G>A p.A711T (on ENST00000488653; = p.A663T on NM_022757.5) | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59947141; called by muse, mutect2, varscan2
- CHRFAM7A | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755923345, COSV100241521; called by muse, mutect2, varscan2
- CNTNAP2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771028883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE7 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs775569816; called by muse, mutect2, varscan2
- HSPG2 | c.5054G>A p.R1685Q | Missense Mutation (SNP) | VAF 128/244 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1442381853; called by muse, mutect2, varscan2
- IGLV3-1 | c.145A>T p.K49* | Nonsense Mutation (SNP) | VAF 73/76 reads (96%) | catalogued as rs192957059; called by muse, mutect2, varscan2
- LIG3 | c.2588C>A p.S863Y | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV99253009; called by muse, mutect2, varscan2
- MEX3B | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs1379126036; called by muse, mutect2, varscan2
- OR5M1 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 176/540 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs572206740, COSV101591529; called by muse, mutect2, varscan2
- PCLO | c.4425G>T p.R1475S | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV61665196; called by muse, mutect2
- PNMA8A | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs749325249, COSV100562413; called by muse, mutect2, varscan2
- RASAL3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.169); catalogued as COSV54605520; called by muse, mutect2, varscan2
- RBM25 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.885); catalogued as rs928079204; called by muse, mutect2, varscan2
- SCN5A | c.5878C>T p.L1960F (on ENST00000333535 / NM_198056.3; = p.L1959F on NM_000335.5) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61121648; called by muse, mutect2, varscan2
- TRIL | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as rs751772436; called by muse, mutect2, varscan2
- WDR7 | c.3211G>A p.A1071T | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs780563895, COSV54348295; called by muse, mutect2, varscan2
- ZNF480 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 70/1140 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1168850473, COSV57996286; called by muse, mutect2
- ACTR3C | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ALOX15B | c.1807G>T p.V603F | Missense Mutation (SNP) | VAF 64/67 reads (96%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARAP2 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- C4orf54 | c.3158T>C p.L1053P | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EYS | c.200_219del p.D67Gfs*20 | Frame Shift Del (DEL) | VAF 104/262 reads (40%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FZD3 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN2 | c.1064A>G p.H355R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- IL18BP | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KATNAL2 | c.447T>A p.N149K (on ENST00000356157 / NM_001353899.1; = p.N77K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LYPLA2 | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 77/412 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NBEAL2 | c.3508G>C p.G1170R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OBSL1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PIK3R4 | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLEKHA7 | c.622A>T p.S208C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN5A | c.3227A>C p.Q1076P | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC16B | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK1 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SIDT2 | c.309T>A p.F103L | Missense Mutation (SNP) | VAF 171/738 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TP53 | c.899_916del p.P300_K305del | In Frame Del (DEL) | VAF 50/114 reads (44%) | called by pindel, varscan2
- WHRN | c.1998C>A p.D666E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ASPHD1 | c.378C>T p.G126= | Silent (SNP) | VAF 89/168 reads (53%) | catalogued as rs746155134; called by muse, mutect2, varscan2
- BCO2 | c.1737C>A p.I579= | Silent (SNP) | VAF 74/314 reads (24%) | called by muse, mutect2, varscan2
- CCDC7 | c.651C>G p.S217= | Silent (SNP) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- CNTN5 | c.2142G>A p.L714= | Silent (SNP) | VAF 99/201 reads (49%) | catalogued as COSV54308434; called by muse, mutect2, varscan2
- FAT3 | c.7989G>A p.K2663= | Silent (SNP) | VAF 62/429 reads (14%) | catalogued as COSV53079327; called by muse, mutect2, varscan2
- FLT3 | c.1296G>A p.T432= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs769234618; called by muse, mutect2
- GJA1 | c.810C>A p.G270= | Silent (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- HSPG2 | c.11442C>T p.S3814= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs562275583; called by muse, mutect2, varscan2
- KCNA5 | c.177C>T p.D59= | Silent (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- KLHL29 | c.1014A>G p.R338= | Silent (SNP) | VAF 58/275 reads (21%) | called by muse, mutect2, varscan2
- MTNR1A | c.666A>G p.K222= | Silent (SNP) | VAF 73/137 reads (53%) | called by muse, mutect2, varscan2
- MTR | c.123C>T p.I41= | Silent (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- MYH4 | c.414G>A p.E138= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as rs1222817978; called by muse, mutect2, varscan2
- NYAP1 | c.1338C>T p.A446= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as rs374505480; called by muse, mutect2, varscan2
- PHF2 | c.942C>T p.F314= | Silent (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.300C>T p.L100= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs368421412; called by muse, mutect2
- SUGP2 | c.2028G>A p.P676= | Silent (SNP) | VAF 89/261 reads (34%) | catalogued as rs772360400, COSV58256620; called by muse, mutect2, varscan2
- TRBV7-4 | c.15C>T p.L5= | Silent (SNP) | VAF 50/233 reads (21%) | catalogued as rs772611580; called by muse, mutect2, varscan2
- TRIML2 | c.438G>A p.K146= | Silent (SNP) | VAF 92/170 reads (54%) | called by muse, mutect2, varscan2
- UNC80 | c.2451T>C p.R817= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- WDFY3 | c.9600C>T p.N3200= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- AC005008.1 | chr7:81190075 A>C | 5'Flank (SNP) | VAF 133/286 reads (47%) | called by muse, mutect2, varscan2
- AC092718.3 | c.*88C>G | 3'UTR (SNP) | VAF 25/601 reads (4%) | catalogued as rs1363271444; called by muse, mutect2
- AC114940.2 | chr5:106543790 C>A | 5'Flank (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- ADAMTS12 | c.*2496G>C | 3'UTR (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99202915 C>T | 3'Flank (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- APBB1 | c.*353del | 3'UTR (DEL) | VAF 23/191 reads (12%) | called by pindel, varscan2
- APBB1 | c.*346C>T | 3'UTR (SNP) | VAF 25/179 reads (14%) | catalogued as rs1358338093; called by muse, varscan2
- ATG12 | c.*1565C>T | 3'UTR (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*2780C>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | catalogued as rs1266110404; called by muse, mutect2, varscan2
- BDH2 | c.419-74T>G | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- BLMH | c.1217-167C>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- CCDC25 | c.*1860A>T | 3'UTR (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2, varscan2
- CCR1 | c.*1247G>A | 3'UTR (SNP) | VAF 118/241 reads (49%) | called by muse, mutect2, varscan2
- CNTN3 | c.*1114A>G | 3'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- CSNK1E | c.885+848G>A | Intron (SNP) | VAF 11/55 reads (20%) | called by muse, varscan2
- DAAM2 | c.429-9G>A | Intron (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- DBR1 | c.-12C>T | 5'UTR (SNP) | VAF 4/91 reads (4%) | catalogued as COSV99604618; called by muse, mutect2
- DCLK1 | c.1944+186C>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2
- DIP2C | c.85+38095T>C | Intron (SNP) | VAF 141/542 reads (26%) | called by muse, mutect2, varscan2
- ELAC2 | c.984-72C>T | Intron (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ELAVL2 | chr9:23690347 G>T | 3'Flank (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- FBXO32 | c.*2993C>T | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- FYCO1 | c.*531del | 3'UTR (DEL) | VAF 64/157 reads (41%) | called by mutect2, pindel, varscan2
- HAUS1 | c.*140G>A | 3'UTR (SNP) | VAF 78/156 reads (50%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*2696C>T | 3'UTR (SNP) | VAF 114/237 reads (48%) | catalogued as rs998247465; called by muse, mutect2, varscan2
- KCNMA1 | c.*1476dup | 3'UTR (INS) | VAF 42/106 reads (40%) | called by mutect2, pindel, varscan2
- LECT2 | c.*248G>A | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- LTB | c.162+61G>A | Intron (SNP) | VAF 44/94 reads (47%) | catalogued as rs932462715; called by muse, mutect2, varscan2
- MIR124-1 | n.36T>G | RNA (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- NEFM | chr8:24913458 C>T | 5'Flank (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- NFASC | c.*104A>T | 3'UTR (SNP) | VAF 80/188 reads (43%) | called by muse, mutect2, varscan2
- NR2F1 | c.*674C>A | 3'UTR (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87873527 A>T | 3'Flank (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- PCDH10 | c.*1067A>C | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157027 C>T | 3'Flank (SNP) | VAF 139/428 reads (32%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1940T>C | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2
- PMP2 | c.*2942G>T | 3'UTR (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- POU6F2 | c.18+27622A>G | Intron (SNP) | VAF 98/187 reads (52%) | called by muse, mutect2, varscan2
- RABL6 | chr9:136807824 ins GCCC | 5'Flank (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel
- RANBP3L | c.-226T>C | 5'UTR (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- RIPOR3 | chr20:50585876 A>T | 3'Flank (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- RNF38 | c.*663T>C | 3'UTR (SNP) | VAF 65/94 reads (69%) | called by muse, mutect2, varscan2
- SARDH | c.*144A>C | 3'UTR (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100898413; called by muse, mutect2, varscan2
- SELENOH | chr11:57741503 C>T | 5'Flank (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- SEMA5A | c.*544T>C | 3'UTR (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- SNORD116-19 | n.88G>A | RNA (SNP) | VAF 300/673 reads (45%) | called by muse, mutect2, varscan2
- SNRPD3 | c.*258C>T | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- SPHK2 | c.-114+36T>C | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, varscan2
- TBC1D8B | c.*885G>T | 3'UTR (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- TMEM65 | c.*703dup | 3'UTR (INS) | VAF 70/172 reads (41%) | catalogued as rs573889375; called by mutect2, varscan2
- TMPPE | c.*2228G>T | 3'UTR (SNP) | VAF 68/178 reads (38%) | called by muse, mutect2
- TMX1 | c.*754dup | 3'UTR (INS) | VAF 14/101 reads (14%) | called by mutect2, varscan2
- TTC17 | c.*994C>G | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- TTC6 | c.357+1687del | Intron (DEL) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- UNC5D | c.*4138C>A | 3'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- USP38 | c.2967+193G>C | Intron (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- VPS13D | c.*85C>T | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- ZNF23 | c.143-1014C>A | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ZNF483 | c.*1270del | 3'UTR (DEL) | VAF 18/138 reads (13%) | called by mutect2, varscan2
- ZRANB2 | chr1:71081259 A>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
